Surgical pathology report (de-identified scan), CDDP_EAGLE case CDDP-ABK3, project CDDP_EAGLE-1 (CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2)), specimen CDDP-ABK3-TTP1-A (Primary Tumor).

Material description

- A) Right upper lobe, lung
- B) Pretracheal e retrotracheale lymph nodes
- C) Lower paratracheal lymph nodes
- D) Subcarinal Metastases
- E) Iliac lymph nodes

CDDP-YP-ABK3-01-PR

Macro description

A) Pulmonary lobe of 190 grams and 12.5 x 10 x 5.5 cm, with pleura focally retracted and dusty, arrived with surgical injury of 6,5 cm of bigger axis

Just before the pleura there is grayish neoformation, elastic compactness, soft margins, 7,5 cm of bigger axis, far 2,5 cm from bronchial margin.

The remaining parenchyma is congested.

We close off n. 10 peribronchial lymph nodes

(A1 bronchial and vascular margins, A2-A4 pleural neoformation, A5 neoformation, A6 parenchyma at distance, A7-A9 peribronchial lymph nodes)

B) Lymph node of 0.8 cm of bigger axis

C) 2 Lymph node fragments between 0.5 cm and 0.9 cm of bigger axis

D) 4 Lymph node fragments between 0.3 cm and 0.7 cm of bigger axis

E) 3 Lymph node fragments between 0.4 cm and 1.4 cm of bigger axis

Micro description

A) Moderately differentiated (G2) lung adenocarcinoma with clear infiltrating the visceral pleura. Margins of resection free of neoplasm.

Metastases in 1 peribronchial lymph node.

B-C-D-E) Unscathed from metastases every lymph node examined.

Staging TNM:
pT2,N1

ICD-0-3

adenocarcinoma, NOS 8140/3

Site: (R) lung, upper lobe C34.1

ICD-10

C34.11

hw 2/9/16

Source: NCI Genomic Data Commons file 7b8bf4d9-939f-489e-bf04-3ed73c15d840 (CDDP-ABK3-TTP1.550649D2-6617-41DC-A1DD-5A56EE862084.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).